Somatic mutation profile of tumor specimen TCGA-DJ-A2QB-01A (aliquot TCGA-DJ-A2QB-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2QB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 53.7 years (19,601 days).
Specimen TCGA-DJ-A2QB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e804fa99-44b1-47bd-a7a0-08198d4678ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2QB-10A (Blood Derived Normal), aliquot TCGA-DJ-A2QB-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9736da0-f67c-4c87-abdb-6c76f770eb20

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD163L1 | c.4182A>T p.R1394S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV58016096; called by mutect2, varscan2
- CDKN2C | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52954815; called by muse, mutect2, varscan2
- DSTYK | c.2106-2A>C p.X702_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV65686513; called by muse, varscan2
- LARS1 | c.1598A>G p.D533G (on ENST00000394434 / NM_020117.11; = p.D506G on NM_016460.3) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV50976066; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.752A>G p.E251G (on ENST00000259318 / NM_001136562.3; = p.E482G on NM_007203.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99394506; called by mutect2, varscan2
- PLXNB2 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV63781701, COSV63782522; called by muse, mutect2, varscan2
- TRPV5 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as COSV54685743; called by muse, mutect2, varscan2
- FAF2 | c.633del p.S212Lfs*24 | Frame Shift Del (DEL) | VAF 28/101 reads (28%) | called by mutect2, pindel, varscan2
- PHKA2 | c.2363_2370del p.G788Vfs*19 | Frame Shift Del (DEL) | VAF 32/167 reads (19%) | called by mutect2, pindel, varscan2
